FM case AD17945 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/92571692-cad9-4f8d-b154-a1e09a07e758

Male, 59.8 years: Papillary renal cell carcinoma (ICD-O-3 8260/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
